Somatic mutation profile of tumor specimen HCM-BROD-0002-C71-01A (aliquot HCM-BROD-0002-C71-01A-01D-A768-36) from HCMI case HCM-BROD-0002-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,213 days).
Specimen HCM-BROD-0002-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42fb3e25-53e6-4655-a662-adce6ad95e03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0002-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0002-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/329fc967-4e37-4279-aef5-f9c0f7eec25b

The open-access MAF lists 95 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Intron 5, Frame Shift Del 4, Nonsense Mutation 4, 3'UTR 3, 5'UTR 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 391/565 reads (69%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 602/849 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 316/788 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99927139; called by muse, mutect2, varscan2
- ARHGAP44 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52390291; called by muse, mutect2
- BRF2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 180/436 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144896527; called by muse, mutect2, varscan2
- CEACAM3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 150/198 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs528553937; called by muse, mutect2, varscan2
- CNR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 330/776 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs201049279; called by muse, mutect2, varscan2
- EDAR | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 264/635 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs148212997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELFN1 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 227/904 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1206191418; called by muse, mutect2, varscan2
- FAT4 | c.12706C>T p.R4236* | Nonsense Mutation (SNP) | VAF 57/1209 reads (5%) | catalogued as rs942135672, COSV58694198; called by muse, mutect2
- FBXO25 | c.384G>A p.L128= (on ENST00000382824 / NM_183421.2; = p.L61= on NM_012173.3) | Splice Region (SNP) | VAF 96/247 reads (39%) | catalogued as rs377735335; called by muse, mutect2, varscan2
- GALNT14 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 330/699 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1422310831, COSV100203898, COSV61110516; called by muse, mutect2, varscan2
- IL17F | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 450/1168 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs550486674, COSV60233991; called by muse, mutect2, varscan2
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 322/738 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2, varscan2
- KSR2 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 374/936 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550563327, CM1311380; called by muse, mutect2, varscan2
- LIPH | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 166/496 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99956296; called by muse, mutect2, varscan2
- MYO1D | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772624904, COSV100554719; called by muse, mutect2, varscan2
- OBSCN | c.9697C>T p.R3233C | Missense Mutation (SNP) | VAF 436/1140 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367605500; called by muse, mutect2, varscan2
- OR6A2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 187/679 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs778988808, COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 420/553 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- PRKACG | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 329/855 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370025582; called by muse, mutect2, varscan2
- PTPRQ | c.6830A>T p.Q2277L (on ENST00000616559; = p.Q2244L on NM_001145026.2) | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57049635; called by muse, mutect2, varscan2
- RP1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs971203515; called by muse, mutect2, varscan2
- SCIN | c.883G>A p.V295I (on ENST00000297029 / NM_001112706.3; = p.V48I on NM_033128.3) | Missense Mutation (SNP) | VAF 141/678 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs543074443; called by muse, mutect2, varscan2
- STK31 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 172/925 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs150391003; called by muse, mutect2, varscan2
- TANC2 | c.4603C>T p.P1535S | Missense Mutation (SNP) | VAF 17/498 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs866965328, COSV67334845; called by muse, mutect2
- TBC1D8 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 368/906 reads (41%) | catalogued as rs747957096, COSV65210358; called by muse, mutect2, varscan2
- TCHH | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 44/772 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs367821937; called by muse, mutect2
- TDRD7 | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 25/637 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1298509646; called by muse, mutect2
- TENT5C | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 394/910 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750792861, COSV65616442; called by muse, mutect2, varscan2
- TMEM43 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 453/1163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758817244; called by muse, mutect2, varscan2
- TOLLIP | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 98/416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55136740; called by muse, mutect2, varscan2
- TRIP6 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 206/1043 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52341842; called by muse, mutect2, varscan2
- TTC29 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs1454013515; called by muse, mutect2, varscan2
- TTN | c.37478G>A p.R12493Q (on ENST00000591111; = p.R5069Q on NM_003319.4) | Missense Mutation (SNP) | VAF 236/598 reads (39%) | PolyPhen benign (0.001); catalogued as rs764083952, COSV59943321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAND5 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 179/499 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV99428445; called by muse, mutect2, varscan2
- ACTR2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 249/427 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ADAM22 | c.2320del p.Y774Mfs*2 | Frame Shift Del (DEL) | VAF 107/474 reads (23%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1779A>T p.K593N (on ENST00000611781; = p.K537N on NM_052997.2) | Missense Mutation (SNP) | VAF 187/470 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.05); called by muse, varscan2
- CLUAP1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 100/220 reads (45%) | called by muse, mutect2, varscan2
- CTSV | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CYP4X1 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DCDC1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 271/582 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DEK | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 132/400 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DQX1 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 44/916 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- DST | c.8906T>C p.L2969P | Missense Mutation (SNP) | VAF 152/359 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- EGFR | c.1548G>C p.W516C | Missense Mutation (SNP) | VAF 36/1098 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHX4 | c.1084del p.D362Ifs*12 | Frame Shift Del (DEL) | VAF 46/107 reads (43%) | called by mutect2, varscan2
- ERLEC1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 546/1041 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- EVC2 | c.1867del p.L623Sfs*38 | Frame Shift Del (DEL) | VAF 294/912 reads (32%) | called by mutect2, pindel, varscan2
- GALNT13 | c.884T>A p.F295Y | Missense Mutation (SNP) | VAF 158/411 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MSL3 | c.645del p.K215Nfs*26 (on ENST00000312196 / NM_078629.4; = p.K49Nfs*26 on NM_006800.4) | Frame Shift Del (DEL) | VAF 146/184 reads (79%) | called by mutect2, pindel*, varscan2
- NOP58 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- OR52M1 | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PFKFB3 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 51/372 reads (14%) | PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PRAMEF7 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 537/660 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PRUNE2 | c.2403T>G p.S801R | Missense Mutation (SNP) | VAF 28/602 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- PTPN23 | c.3578_3579insA p.V1194Cfs*12 | Frame Shift Ins (INS) | VAF 242/654 reads (37%) | called by mutect2, pindel, varscan2
- RFTN1 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 252/626 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SATL1 | c.787G>T p.V263F (on ENST00000395409; = p.V450F on NM_001012980.2) | Missense Mutation (SNP) | VAF 399/530 reads (75%) | SIFT tolerated (0.7); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC45A2 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 403/999 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPV6 | c.1591A>C p.M531L | Missense Mutation (SNP) | VAF 332/1692 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFP92 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 373/440 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZNF735 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 328/1672 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACSM5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 447/1021 reads (44%) | catalogued as rs369835056; called by muse, mutect2, varscan2
- ACTRT1 | c.621C>T p.L207= | Silent (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- ADCY4 | c.531C>T p.N177= | Silent (SNP) | VAF 112/265 reads (42%) | catalogued as rs376126420; called by muse, mutect2, varscan2
- COL1A1 | c.4056G>A p.L1352= | Silent (SNP) | VAF 408/1022 reads (40%) | called by muse, mutect2, varscan2
- DLK1 | c.1014C>A p.R338= | Silent (SNP) | VAF 159/402 reads (40%) | called by muse, mutect2, varscan2
- ECE2 | c.177G>A p.T59= | Silent (SNP) | VAF 161/412 reads (39%) | called by muse, mutect2, varscan2
- FAM124B | c.1140C>T p.G380= | Silent (SNP) | VAF 366/845 reads (43%) | catalogued as rs375635395; called by muse, mutect2, varscan2
- FZD9 | c.54G>A p.A18= | Silent (SNP) | VAF 24/271 reads (9%) | called by muse, mutect2
- KRT14 | c.144C>T p.G48= | Silent (SNP) | VAF 254/571 reads (44%) | catalogued as rs1254536871, COSV51421894; called by muse, mutect2, varscan2
- NLRP7 | c.792G>A p.A264= | Silent (SNP) | VAF 321/456 reads (70%) | catalogued as rs141553552; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1428C>T p.D476= (on ENST00000259318 / NM_001136562.3; = p.D707= on NM_007203.5) | Silent (SNP) | VAF 168/396 reads (42%) | catalogued as rs552999944; called by muse, mutect2, varscan2
- PAX4 | c.465C>T p.P155= | Silent (SNP) | VAF 56/1568 reads (4%) | catalogued as COSV100489907, COSV100490161; called by muse, mutect2
- PBX4 | c.501G>A p.R167= | Silent (SNP) | VAF 147/449 reads (33%) | called by muse, mutect2, varscan2
- PCDH9 | c.3273C>T p.D1091= (on ENST00000377865 / NM_203487.3; = p.D1057= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/575 reads (7%) | catalogued as rs372281341; called by muse, mutect2
- SNED1 | c.3603C>T p.G1201= | Silent (SNP) | VAF 376/901 reads (42%) | catalogued as rs369849516; called by muse, varscan2
- SYDE1 | c.1911C>T p.P637= | Silent (SNP) | VAF 393/659 reads (60%) | called by muse, mutect2, varscan2
- TCEAL6 | c.303G>T p.P101= | Silent (SNP) | VAF 174/498 reads (35%) | catalogued as rs782134556; called by muse, mutect2, varscan2
- TJP2 | c.1044C>T p.D348= | Silent (SNP) | VAF 247/696 reads (35%) | catalogued as rs750420311; called by muse, mutect2, varscan2
- USH2A | c.13434A>G p.E4478= | Silent (SNP) | VAF 351/910 reads (39%) | called by muse, mutect2, varscan2
- WDR13 | c.483G>A p.A161= | Silent (SNP) | VAF 261/325 reads (80%) | catalogued as rs1009484702; called by muse, mutect2, varscan2
- XIRP2 | c.5994A>G p.G1998= (on ENST00000628543; = p.G2173= on NM_152381.6) | Silent (SNP) | VAF 31/509 reads (6%) | called by muse, mutect2
- FAM227B | c.1013-24889G>A | Intron (SNP) | VAF 45/56 reads (80%) | catalogued as rs555267524; called by muse, mutect2, varscan2
- FAS | c.*1303C>A | 3'UTR (SNP) | VAF 108/146 reads (74%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8501G>T | Intron (SNP) | VAF 50/398 reads (13%) | called by muse, varscan2
- KRT14 | c.1322-25C>G | Intron (SNP) | VAF 160/440 reads (36%) | called by muse, mutect2
- LYNX1-SLURP2 | c.*202C>A | 3'UTR (SNP) | VAF 203/447 reads (45%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85808A>G | Intron (SNP) | VAF 51/1281 reads (4%) | called by muse, mutect2
- NKD2 | c.*44C>T | 3'UTR (SNP) | VAF 388/952 reads (41%) | catalogued as rs762186974; called by muse, varscan2
- NPIPP1 | n.914C>G | RNA (SNP) | VAF 852/2437 reads (35%) | catalogued as rs759043989, COSV100722054; called by muse, mutect2, varscan2
- SMARCAL1 | c.1711-326G>A | Intron (SNP) | VAF 44/178 reads (25%) | catalogued as rs1326414347, COSV61924553; called by muse, mutect2, varscan2
- SUCO | c.-231C>G | 5'UTR (SNP) | VAF 25/385 reads (6%) | called by muse, mutect2
